Surgical pathology report (de-identified scan), TCGA case TCGA-PT-A8TR, project TCGA-SARC (Sarcoma), tissue source site Maine Medical Center, specimen TCGA-PT-A8TR-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

SOFT TISSUE: MALIGNANT, LEIOMYOSARCOMA, MYXOID

(A and D) Uterus, bilateral ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy:

-Myxoid leiomyosarcoma involving lower uterine segment. See comment.

-Endometrium: Inactive endometrium.

-Myometrium: Adenomyosis.

-Ovaries: Focal surface endometriosis of one ovary.

-Fallopian tubes: Paratubal cysts.

-pTN stage based on available material: pT1bN0.

*ICD O-3
Leiomyosarcoma myxoid 8896/3
Site Lower uterine segment C54.0
pT1bN0 11/27/14*

(B) Right pelvic lymph node, excision: One benign lymph node (0/1).

(C) Left pelvic lymph node, excision: One benign lymph node (0/1).

COMMENT:

The specimen is received markedly fragmented and it is difficult to determine the exact size of leiomyosarcoma (at least 14 cm). Tumor is composed of cords of moderately to highly atypical spindle cells in a background of loose myxoid stroma with prominent hyalinization. There is no necrosis. Mitotic rate is up to 3 per 10 HPF. Parametrial soft tissue and bordering myometrium show infiltrative nature of this neoplasm. Tumor is positive for desmin and vimentin and is negative for muscle specific actin, caldesmon, CD34, CD10 and CD117. Morphology and immunoprofile are most supportive of the diagnosis of myxoid leiomyosarcoma. Myxoid leiomyosarcomas usually display low mitotic rate, no necrosis and moderately atypical cytology of tumor cells.

CLINICAL HISTORY: Pelvic mass.

GROSS DESCRIPTION:

(A) The specimen is received fresh labeled _____ and portion of uterus, right tube and ovary. It consists of an ovoid pink-red friable mass, multiple friable fragments of pink-red soft tissue, blood clot, and separate fallopian tube and ovary. The fragments weigh in aggregate 1125 grams. The largest fragment measures 16.0 x 14.7 x 7.5 cm and the separate fragments measure in aggregate 19.0 x 15.0 x 3.0 cm. No discernable uterine tissue is identified. A representative portion is submitted for frozen section. Sectioning reveals glistening mucoid pink-tan to purple friable cut surfaces. The detached ovary measures 2.3 x 1.7 x 1.0 cm and the fimbriated fallopian tube measures 4.0 cm in length by 0.5 cm in diameter. The ovary weighs 3 gram, demonstrating a cerebriform pink glistening surface. Sectioning reveals an unremarkable pink-tan fibrous cut surface. The fallopian tube has a pink-red surface with focal adhesions and a paratubal cyst measuring 1.8 cm in greatest dimension, filled with yellow fluid. Sectioning reveals an unremarkable pink-tan cut surface. No involvement of the fallopian tube or ovary by the mass is identified.

Representative sections are submitted:

1. frozen section remnant
- 2-15. representative mass
16. ovary and fallopian tube

(B) The specimen is received in formalin labeled _____ and right pelvic lymph node. It is a lymph node measuring 0.5 cm.

[page 2 of 2]
(C) The specimen is received unfixed labeled _____ and left pelvic lymph node. It is a soft piece of red tissue measuring 1.2 x 1.0 x 0.3 cm.

(D) The specimen is received fresh labeled _____ and remainder of uterus and right adnexa. It consists of a uterine fundus with attached ovary and fallopian tube, attached friable pink-tan mass, and multiple irregular detached friable fragments of tumor. The uterine fundus measures 6.0 x 3.5 x 2.5 cm with the mass demonstrating exposed contents on the inferior aspect extending out the left parametrial soft tissue, measuring 13.5 x 6.5 x 6.0 cm. The separate fragments of mass measure in aggregate 13.0 x 12.0 x 4.0 cm and all the fragments together weigh 390 grams. The endometrial mucosa is pink and glistening, measuring 0.1 cm in thickness. The myometrium is pink, rubbery and trabeculated. The ovary measures 3.2 x 1.2 x 0.8 cm, weighing 4 grams and demonstrating a smooth surface. Sectioning reveals an unremarkable pink-tan fibrous cut surface with no mass involvement identified. The attached fimbriated fallopian tube has been previously ligated, measuring 4.0 cm in length by 0.7 cm in diameter, demonstrating a pink-tan surface with a single paratubal cyst measuring 0.2 cm in greatest dimension. Sectioning reveals an unremarkable pink-tan cut surface with no mass involvement identified. Sectioning the fragments of tumor reveal pink mucoid glistening friable gritty cut surfaces. Representative sections are submitted as follows:

- 1-2. endomyometrium
3. mass to parametrial soft tissue/myometrium
- 4 ovary and fallopian
- 5 mass to parametrial soft tissue/myometrium
- 6-7. representative parametrial tumor
- 8-9. representative additional fragments of tumor

Clinical History:

Age:

Sex: Female

Race: Caucasian

pStage: IA

YOB:

Surgery:

End of Report for:

Source: NCI Genomic Data Commons file b020915b-67fd-48e9-bb8a-20a92f681320 (TCGA-PT-A8TR.96EF7059-A09F-43B3-9E86-1CF0C3493482.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).